Somatic mutation profile of cancer-model specimen HCM-CSHL-0377-C18-85A (3D Organoid; aliquot HCM-CSHL-0377-C18-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0377-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 69.7 years (25,463 days).
Specimen HCM-CSHL-0377-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8df3418b-7498-4289-9592-e641c12f66dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0377-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0377-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/978d0596-6422-4768-9993-200eda963f6c

The open-access MAF lists 2,111 somatic variants for this specimen: 1,385 protein-altering or splice-affecting, 411 silent, 315 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 909, Silent 411, Frame Shift Del 285, Intron 168, Frame Shift Ins 79, Nonsense Mutation 51, 3'UTR 50, 5'UTR 44, Splice Site 22, Splice Region 20, RNA 19, 5'Flank 19.

Variants (750 of 2,111; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG2 | c.1545dup p.E516* (on ENST00000379869 / NM_001079858.3; = p.E513* on NM_005756.4) | Frame Shift Ins (INS) | VAF 64/69 reads (93%) | catalogued as rs774488954; ClinVar: pathogenic; called by mutect2, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 134/276 reads (49%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, varscan2
- CRPPA | c.165del p.C56Afs*35 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs1554371369; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FKRP | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1247934219, CM073068, CM074872; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 44/90 reads (49%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 120/264 reads (45%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 204/220 reads (93%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 182/434 reads (42%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC13A5 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1202091819; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918642, CM910358, CM910359, COSV63752484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.2672del p.N891Tfs*40 | Frame Shift Del (DEL) | VAF 99/257 reads (39%) | catalogued as rs118203724, CD1111250, COSV53764493; ClinVar: not provided / pathogenic; called by pindel, varscan2
- TUBGCP6 | c.3893dup p.G1299Wfs*69 | Frame Shift Ins (INS) | VAF 97/226 reads (43%) | catalogued as rs760024638; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 210/434 reads (48%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCB1 | c.1002A>T p.V334= | Splice Region (SNP) | VAF 140/312 reads (45%) | catalogued as rs200049706; called by muse, mutect2, varscan2
- ABCC1 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778697425, COSV60686300; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as rs748616526; called by muse, mutect2, varscan2
- ABRAXAS1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs549027065; called by muse, mutect2, varscan2
- AC055839.2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as rs560147255; called by muse, mutect2, varscan2
- AC134980.2 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60907989; called by mutect2, varscan2
- ACACB | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 109/242 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as rs768750072; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 128/144 reads (89%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM10 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 320/635 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs747308486; called by muse, mutect2, varscan2
- ADAMTS20 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs538139197, COSV67140479; called by muse, mutect2, varscan2
- ADGRA1 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 206/392 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs906519509; called by muse, mutect2
- ADGRE3 | c.762del p.F254Lfs*12 | Frame Shift Del (DEL) | VAF 55/136 reads (40%) | catalogued as rs762974450; called by mutect2, pindel, varscan2
- ADGRL2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 146/351 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54679818; called by muse, mutect2, varscan2
- AEBP1 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs1168034376; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | catalogued as rs757477831; called by mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs778351035; called by pindel, varscan2
- AKAP17A | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.714); catalogued as rs193269079; called by muse, mutect2, varscan2
- ALKBH5 | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99231226; called by muse, mutect2, varscan2
- ALPG | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 186/430 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs150811092; called by muse, varscan2
- ANGPT4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs150174277, COSV67921961; called by muse, mutect2, varscan2
- ANK1 | c.5119G>A p.G1707S | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as rs746486928, COSV55880564; ClinVar: uncertain significance; called by muse, mutect2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 88/193 reads (46%) | catalogued as rs370637835; called by mutect2, varscan2
- ANKFY1 | c.2839G>A p.A947T (on ENST00000341657 / NM_001330063.2; = p.A948T on NM_016376.5) | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs773693184; called by muse, mutect2, varscan2
- ANKRD31 | c.3212A>T p.D1071V | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1313229195; called by muse, mutect2, varscan2
- ANO3 | c.1032+2T>C p.X344_splice | Splice Site (SNP) | VAF 54/135 reads (40%) | catalogued as COSV99881174; called by muse, mutect2, varscan2
- ANOS1 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372392838, COSV52920966; called by muse, mutect2, varscan2
- AP5B1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs376122863, COSV57503073; called by muse, mutect2, varscan2
- AP5B1 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753492805; called by muse, mutect2, varscan2
- APH1A | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs199961673; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs546686089; called by mutect2, varscan2
- AQP7 | c.528G>A p.A176= | Splice Region (SNP) | VAF 38/78 reads (49%) | catalogued as rs528855599, COSV99952055; called by muse, mutect2, varscan2
- ARHGAP39 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1418152699; called by muse, mutect2, varscan2
- ARHGAP4 | c.499-4G>A | Splice Region (SNP) | VAF 128/128 reads (100%) | catalogued as rs1341642627; called by muse, mutect2, varscan2
- ARHGEF17 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs892543833; called by muse, mutect2, varscan2
- ARHGEF17 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 159/328 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038055507; called by muse, mutect2, varscan2
- ARHGEF2 | c.1210C>T p.H404Y (on ENST00000361247 / NM_001162383.2; = p.H376Y on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.342); catalogued as COSV58115239; called by muse, mutect2, varscan2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 145/451 reads (32%) | catalogued as COSV61376881; called by pindel, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 78/174 reads (45%) | catalogued as rs776520069; called by mutect2, varscan2
- ARMC1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 126/301 reads (42%) | catalogued as rs963721845; called by muse, mutect2, varscan2
- ARRDC1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.151); catalogued as rs748392202, COSV58375691; called by muse, mutect2, varscan2
- ASB14 | c.371del p.L124Wfs*8 (on ENST00000389601; = p.L123Wfs*8 on NM_001142733.3) | Frame Shift Del (DEL) | VAF 104/225 reads (46%) | catalogued as rs770471078; called by mutect2, varscan2
- ASCC2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369487758; called by muse, mutect2, varscan2
- ASIC3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 159/309 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs747610290; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 39/86 reads (45%) | catalogued as rs747712363; called by mutect2, varscan2
- ATP5F1C | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV59622288; called by muse, mutect2, varscan2
- ATP5MC3 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as COSV52977316; called by muse, mutect2, varscan2
- ATP8A1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52532212, COSV52539809; called by muse, mutect2, varscan2
- ATP8B4 | c.1676C>A p.S559Y | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99464129; called by muse, mutect2, varscan2
- B3GNT7 | c.1108A>G p.M370V | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs760569261; called by muse, mutect2, varscan2
- BAIAP2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs771522958; called by muse, mutect2, varscan2
- BAIAP2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs201786144; called by muse, mutect2, varscan2
- BARD1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1254403542, COSV53615440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as rs1444509662, COSV58607797; called by muse, varscan2
- BCLAF1 | c.349del p.R117Efs*63 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs764218761; called by mutect2, pindel, varscan2
- BCORL1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 134/135 reads (99%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1373179389, COSV54398446; called by muse, mutect2, varscan2
- BEND3 | c.793dup p.D265Gfs*95 | Frame Shift Ins (INS) | VAF 121/302 reads (40%) | catalogued as rs782111679; called by mutect2, varscan2
- BIN1 | c.496_498del p.K166del | In Frame Del (DEL) | VAF 114/330 reads (35%) | catalogued as rs775374523; called by pindel, varscan2
- BMP6 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 119/213 reads (56%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs756121523, COSV51666044; called by muse, mutect2, varscan2
- BMPR1A | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 164/322 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs556937566; called by muse, mutect2, varscan2
- BOP1 | c.1900_1902del p.N634del | In Frame Del (DEL) | VAF 266/611 reads (44%) | catalogued as rs1564593509; called by mutect2, pindel, varscan2
- BRINP2 | c.661del p.A221Pfs*53 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as COSV64180297; called by mutect2, pindel, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 21/43 reads (49%) | catalogued as rs746043904; called by mutect2, varscan2
- C10orf71 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 153/345 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs375261748; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 52/112 reads (46%) | catalogued as rs771322722; called by mutect2, varscan2
- C12orf42 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 173/375 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372316015, COSV59387580; called by muse, mutect2, varscan2
- C1R | c.1655G>A p.R552H (on ENST00000536053 / NM_001354346.2; = p.R538H on NM_001733.7) | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1334659221, COSV101605620; called by muse, mutect2, varscan2
- C2CD4D | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1010634766; called by muse, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | catalogued as rs752496395; called by mutect2, varscan2
- C5AR1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as rs138808390; called by muse, mutect2, varscan2
- C5orf34 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs144939704; called by muse, mutect2, varscan2
- C8B | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 175/375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs138837336; called by muse, mutect2, varscan2
- CACHD1 | c.1725A>G p.I575M | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51560386; called by muse, mutect2, varscan2
- CACNA1G | c.1546del p.R516Gfs*48 | Frame Shift Del (DEL) | VAF 65/178 reads (37%) | catalogued as rs1401299999; called by mutect2, pindel, varscan2
- CACNA1I | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1016081416; called by muse, mutect2, varscan2
- CAMSAP1 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs199979384; called by muse, mutect2, varscan2
- CAPS | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs142947292; called by muse, mutect2, varscan2
- CARM1 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs201586231, COSV53402800; called by muse, mutect2, varscan2
- CASKIN1 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV58877343; called by muse, mutect2, varscan2
- CAST | c.387dup p.E130Rfs*12 (on ENST00000341926; = p.E213Rfs*12 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 50/118 reads (42%) | catalogued as rs750937315; called by mutect2, pindel, varscan2
- CATSPERD | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 229/469 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200349808, COSV100486725; called by muse, mutect2, varscan2
- CBLN3 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1237538084; called by muse, mutect2, varscan2
- CC2D1B | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs756850623, COSV52559133; called by muse, mutect2, varscan2
- CCAR1 | c.2880+8A>G | Splice Region (SNP) | VAF 59/117 reads (50%) | catalogued as rs1207265311; called by muse, mutect2, varscan2
- CCDC148 | c.1251del p.I418* | Frame Shift Del (DEL) | VAF 44/84 reads (52%) | catalogued as rs758917400; called by mutect2, varscan2
- CCDC151 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 165/368 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1184712064; called by muse, mutect2, varscan2
- CCDC22 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782487743; called by muse, mutect2, varscan2
- CCDC27 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs370107628, COSV53900827; called by muse, mutect2, varscan2
- CCDC51 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371682973; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 122/125 reads (98%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC9 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1232881258; called by muse, mutect2
- CCER2 | c.660C>G p.H220Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1437798213; called by muse, mutect2, varscan2
- CDH16 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs764853742; called by muse, varscan2
- CDK4 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 319/713 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs876660318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5R2 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56935990; called by muse, mutect2, varscan2
- CELSR1 | c.7099C>T p.R2367W | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs538522145, COSV53093892; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP290 | c.4195-3del | Splice Region (DEL) | VAF 37/90 reads (41%) | catalogued as rs748771739; called by mutect2, pindel, varscan2
- CEP350 | c.8475del p.E2826Kfs*39 | Frame Shift Del (DEL) | VAF 63/176 reads (36%) | catalogued as COSV62608100; called by mutect2, pindel, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 65/143 reads (45%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 41/93 reads (44%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP58 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs1411707; called by muse, mutect2, varscan2
- CFAP58 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | catalogued as rs761844995; called by mutect2, pindel, varscan2
- CFAP65 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs772103989, COSV58562929; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 75/169 reads (44%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD3 | c.5521G>A p.E1841K (on ENST00000330494 / NM_001005273.3; = p.E1807K on NM_005852.4) | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313938382; called by muse, mutect2, varscan2
- CHGB | c.630del p.E211Rfs*3 | Frame Shift Del (DEL) | VAF 122/258 reads (47%) | catalogued as rs1568551915; called by mutect2, varscan2
- CHRNA4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 354/720 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs750232429, COSV64720726; called by muse, mutect2, varscan2
- CHRNE | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1359029030, COSV53417164; called by muse, mutect2, varscan2
- CHST12 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 184/361 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1175565150, COSV51676768; called by muse, mutect2, varscan2
- CHST3 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 315/685 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64150890; called by muse, mutect2, varscan2
- CHST8 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV52857826; called by muse, mutect2, varscan2
- CHUK | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 163/358 reads (46%) | catalogued as COSV64918273; called by muse, mutect2, varscan2
- CILP | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.645); catalogued as rs771666368, COSV56022097; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 33/66 reads (50%) | catalogued as rs752250702; called by mutect2, varscan2
- CKLF | c.447dup p.E150Rfs*12 (on ENST00000264001 / NM_016951.4; = p.E65Rfs*12 on NM_016326.3) | Frame Shift Ins (INS) | VAF 100/278 reads (36%) | catalogued as rs754415052; called by mutect2, varscan2
- CLASRP | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0); catalogued as COSV55518602; called by muse, mutect2, varscan2
- CLIC3 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1186813837, COSV100860394; called by muse, mutect2, varscan2
- CLK2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 238/534 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as rs201974382; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 130/279 reads (47%) | catalogued as rs751921758; called by mutect2, varscan2
- CNN2 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 206/455 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs116408565; called by muse, mutect2, varscan2
- CNNM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV63203024; called by muse, mutect2, varscan2
- CNOT3 | c.732del p.S245Afs*90 | Frame Shift Del (DEL) | VAF 58/114 reads (51%) | catalogued as rs753475896; called by mutect2, varscan2
- COG6 | c.1783C>A p.L595I | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV62995347; called by muse, mutect2, varscan2
- COG7 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 170/388 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56149205; called by muse, mutect2, varscan2
- COL19A1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs199945062, COSV59571622; called by muse, mutect2, varscan2
- COPB1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 158/287 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs559842736; called by muse, mutect2, varscan2
- COQ8B | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 118/243 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760103716; called by muse, mutect2, varscan2
- CORO2B | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs751295241, COSV99962942; called by muse, varscan2
- CR1 | c.4481del p.P1494Hfs*51 | Frame Shift Del (DEL) | VAF 60/174 reads (34%) | catalogued as COSV100887848; called by mutect2, pindel, varscan2
- CRLF1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.302); catalogued as rs1439804163; called by muse, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF2RB | c.2684A>C p.E895A | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99453422; called by muse, mutect2, varscan2
- CSMD1 | c.9817+1G>A p.X3273_splice (on ENST00000520002; = p.X3272_splice on NM_033225.6) | Splice Site (SNP) | VAF 61/131 reads (47%) | catalogued as COSV59292120; called by muse, mutect2, varscan2
- CSMD2 | c.8494G>A p.V2832M | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs760039608; called by muse, mutect2, varscan2
- CST7 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774561103, COSV65195674; called by muse, mutect2, varscan2
- CTBP1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 217/469 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs371355192, COSV99337691; called by muse, mutect2, varscan2
- CTBP2 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745561150; called by muse, mutect2, varscan2
- CUEDC1 | c.332del p.P111Rfs*136 | Frame Shift Del (DEL) | VAF 37/85 reads (44%) | catalogued as COSV100804649, COSV64227288; called by mutect2, pindel, varscan2
- CUX2 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 178/393 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400410114, COSV55624216; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs772257590; called by mutect2, varscan2
- CYP2D7 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); catalogued as rs778324262; called by muse, mutect2, varscan2
- DAB2IP | c.1238G>A p.R413Q (on ENST00000408936; = p.R385Q on NM_032552.3) | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1490540211; called by muse, mutect2, varscan2
- DCLK1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs760301962, COSV55184477; called by muse, mutect2, varscan2
- DDX11 | c.2271+5G>A | Splice Region (SNP) | VAF 247/522 reads (47%) | catalogued as rs199779676; called by muse, mutect2, varscan2
- DENND2C | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as rs760314015, COSV101283961; called by muse, mutect2, varscan2
- DENR | c.323del p.K108Rfs*10 | Frame Shift Del (DEL) | VAF 45/97 reads (46%) | catalogued as rs1566061026; called by mutect2, varscan2
- DERL1 | c.671del p.P224Lfs*4 | Frame Shift Del (DEL) | VAF 52/166 reads (31%) | catalogued as rs1314875568; called by mutect2, pindel, varscan2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | catalogued as rs35538077; called by mutect2, varscan2
- DGKE | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV104370104; called by muse, mutect2
- DIAPH3 | c.771+2T>C p.X257_splice | Splice Site (SNP) | VAF 128/318 reads (40%) | catalogued as COSV57369431; called by muse, mutect2, varscan2
- DLEU7 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1310077935; called by muse, mutect2, varscan2
- DMWD | c.1366dup p.L456Pfs*236 | Frame Shift Ins (INS) | VAF 22/52 reads (42%) | catalogued as rs746317972; called by mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.9320G>A p.R3107H (on ENST00000409039; = p.R3046H on NM_207437.3) | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1276943171, COSV101292571; called by muse, mutect2, varscan2
- DNAH2 | c.1689+1G>A p.X563_splice | Splice Site (SNP) | VAF 35/52 reads (67%) | catalogued as COSV50014370; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 243/530 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DNAI1 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54279422; called by muse, mutect2, varscan2
- DOP1B | c.5812C>T p.R1938C | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs536538834, COSV101214937; called by muse, mutect2, varscan2
- DOT1L | c.2806+6G>A | Splice Region (SNP) | VAF 130/342 reads (38%) | catalogued as rs535777073; called by muse, varscan2
- DRICH1 | c.54del p.K19Rfs*26 | Frame Shift Del (DEL) | VAF 206/482 reads (43%) | catalogued as COSV58503898; called by mutect2, varscan2
- DST | c.20495C>T p.A6832V (on ENST00000361203 / NM_001374722.1; = p.A4529V on NM_015548.5) | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs748051176, COSV55009833; called by muse, mutect2, varscan2
- DSTYK | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs374722933; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | catalogued as rs762133243; called by mutect2, varscan2
- DUOX2 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 363/746 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs573487375, COSV101199756; called by muse, mutect2, varscan2
- DUOXA1 | c.348del p.V117Cfs*4 | Frame Shift Del (DEL) | VAF 129/297 reads (43%) | catalogued as COSV50994962; called by mutect2, pindel, varscan2
- DUSP5 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 185/409 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1160733626; called by muse, mutect2, varscan2
- DUSP5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765810015, COSV63646414, COSV63647007; called by muse, mutect2, varscan2
- EBLN1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1015265877; called by muse, mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 30/32 reads (94%) | catalogued as rs752671785; called by mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF2S2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 132/305 reads (43%) | catalogued as COSV66621144; called by muse, mutect2, varscan2
- EIF3A | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs751921377, COSV100974595; called by muse, varscan2
- EIPR1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as rs865933981; called by muse, mutect2, varscan2
- ELAVL2 | c.643del p.L215Ffs*16 | Frame Shift Del (DEL) | VAF 125/297 reads (42%) | catalogued as COSV56370066; called by mutect2, pindel, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 44/98 reads (45%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- ENOSF1 | c.641-8_641-5del | Splice Region (DEL) | VAF 74/184 reads (40%) | catalogued as rs753221027; called by mutect2, pindel, varscan2
- ENTPD6 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs772949313; called by muse, mutect2, varscan2
- EOMES | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 179/421 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746252799; called by muse, mutect2, varscan2
- EPB41L1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 176/326 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs375772370; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 59/137 reads (43%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 38/74 reads (51%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBB3 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 245/562 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs56387488; called by muse, mutect2, varscan2
- ERCC5 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 156/273 reads (57%) | catalogued as CM025986; called by muse, mutect2, varscan2
- ERO1A | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as rs751524739; called by muse, mutect2, varscan2
- ETAA1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781313470; called by muse, mutect2, varscan2
- ETV4 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 150/347 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567705535, COSV52251645; called by muse, mutect2, varscan2
- EXPH5 | c.5540G>A p.R1847Q | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs957461600; called by muse, mutect2, varscan2
- EXT2 | c.1225G>A p.A409T (on ENST00000343631; = p.A442T on NM_000401.3) | Missense Mutation (SNP) | VAF 246/542 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100640718; called by muse, mutect2, varscan2
- EZH2 | c.455del p.N152Ifs*15 | Frame Shift Del (DEL) | VAF 94/288 reads (33%) | catalogued as COSV100235433; called by mutect2, pindel, varscan2
- F2RL3 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 342/692 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs746738735; called by muse, mutect2, varscan2
- FAH | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 252/557 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV99930567; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 64/414 reads (15%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM151A | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV56364423; called by muse, mutect2, varscan2
- FAM162A | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.832); catalogued as rs947256688; called by muse, mutect2, varscan2
- FAM181B | c.1021dup p.R341Pfs*96 | Frame Shift Ins (INS) | VAF 17/33 reads (52%) | catalogued as rs770611228; called by mutect2, pindel, varscan2
- FAM209B | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 238/491 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV64915257; called by muse, varscan2
- FAM20C | c.212del p.P71Rfs*59 | Frame Shift Del (DEL) | VAF 66/153 reads (43%) | catalogued as rs1341876798; called by mutect2, pindel, varscan2
- FAM47C | c.2003del p.P668Rfs*157 | Frame Shift Del (DEL) | VAF 192/342 reads (56%) | catalogued as COSV63729354; called by pindel, varscan2
- FAM53C | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53512168; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT1 | c.5630del p.P1877Lfs*20 | Frame Shift Del (DEL) | VAF 46/99 reads (46%) | catalogued as COSV71676103; called by mutect2, pindel, varscan2
- FAT1 | c.4790T>C p.V1597A | Missense Mutation (SNP) | VAF 169/290 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV101499113; called by muse, mutect2, varscan2
- FAT3 | c.10051A>G p.S3351G | Missense Mutation (SNP) | VAF 133/258 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs774871409; called by muse, mutect2, varscan2
- FAT4 | c.13661A>G p.E4554G | Missense Mutation (SNP) | VAF 142/291 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs780893557, COSV58688269; called by muse, mutect2, varscan2
- FBN1 | c.6845G>A p.R2282Q | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as rs759696323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.1439del p.G480Dfs*9 | Frame Shift Del (DEL) | VAF 83/238 reads (35%) | catalogued as COSV52499778; called by mutect2, pindel, varscan2
- FBXL20 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52901883; called by muse, mutect2, varscan2
- FBXW5 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 276/614 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1408991520; called by muse, mutect2, varscan2
- FCGR2B | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369138204; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | catalogued as rs748969702; called by mutect2, varscan2
- FEV | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 181/353 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55386546; called by muse, mutect2, varscan2
- FEZF2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV51863369; called by muse, mutect2, varscan2
- FGD3 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs528777144; called by muse, mutect2, varscan2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 344/737 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2, varscan2
- FGF3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 207/424 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs782297586; called by muse, mutect2, varscan2
- FHOD1 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.498); catalogued as rs749236488; called by muse, mutect2, varscan2
- FHOD3 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs750825580, COSV57163299; called by muse, varscan2
- FIG4 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1562654327; called by muse, mutect2, varscan2
- FLRT2 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV100420698; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 37/66 reads (56%) | catalogued as rs769482947; called by mutect2, varscan2
- FLVCR2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 322/660 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs772508772, COSV53163538; called by muse, mutect2, varscan2
- FN1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 237/502 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs761729774, COSV60550427; called by muse, mutect2, varscan2
- FN1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 167/441 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.523); catalogued as rs746000539; called by muse, mutect2, varscan2
- FN3KRP | c.65del p.G22Afs*19 | Frame Shift Del (DEL) | VAF 84/211 reads (40%) | catalogued as rs753495515; called by mutect2, pindel, varscan2
- FOXD4L4 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 328/1832 reads (18%) | catalogued as rs1431669883; called by muse, varscan2
- FOXE1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs886732503; called by muse, mutect2, varscan2
- FOXK1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 122/233 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1003844502, COSV61068538; called by muse, mutect2, varscan2
- FREM3 | c.5389C>T p.R1797C | Missense Mutation (SNP) | VAF 158/319 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as rs369671725; called by muse, mutect2, varscan2
- FSD1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs145440493; called by muse, mutect2, varscan2
- FTMT | c.136del p.R46Afs*63 | Frame Shift Del (DEL) | VAF 64/175 reads (37%) | catalogued as rs765331335; called by mutect2, pindel, varscan2
- FURIN | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs143865091; called by muse, mutect2, varscan2
- FUT8 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs762317080; called by muse, mutect2, varscan2
- FZD1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1563008272, COSV55312341; called by muse, mutect2, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as rs772301203; called by mutect2, varscan2
- GADD45A | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1266528144, COSV100921463; called by muse, mutect2, varscan2
- GAK | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149432967; called by muse, mutect2, varscan2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 73/174 reads (42%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GATA5 | c.248del p.P83Qfs*64 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs1555897019; called by mutect2, pindel, varscan2
- GBA2 | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 72/145 reads (50%) | catalogued as rs769952538; called by muse, mutect2, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 174/181 reads (96%) | catalogued as rs761897305; called by mutect2, varscan2
- GGA2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs771058001, COSV59167678; called by muse, mutect2, varscan2
- GK3P | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 189/382 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764206073, COSV56983100; called by muse, mutect2, varscan2
- GLI2 | c.596del p.G199Afs*25 | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | catalogued as COSV100082956, COSV58045188; called by mutect2, pindel
- GLIS1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs144490309, COSV56547496; called by muse, mutect2, varscan2
- GLTP | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs375791569; called by muse, mutect2, varscan2
- GOLIM4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.115); catalogued as rs751158252; called by muse, mutect2, varscan2
- GPR180 | c.9del p.L4_?3 | Frame Shift Del (DEL) | VAF 61/146 reads (42%) | catalogued as rs772740445; called by mutect2, pindel, varscan2
- GPR183 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs755906669, COSV100854329, COSV100854417; called by muse, mutect2, varscan2
- GPR68 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs774609124, COSV99473354; called by muse, mutect2, varscan2
- GRAMD1A | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774467744, COSV58767297; called by muse, mutect2, varscan2
- GRIK1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as rs768882503; called by muse, mutect2, varscan2
- GRIP1 | c.1633C>T p.R545* (on ENST00000359742 / NM_001379345.1; = p.R493* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 183/378 reads (48%) | catalogued as rs1452438437, COSV54021454; called by muse, mutect2, varscan2
- GRM1 | c.2399C>A p.A800D | Missense Mutation (SNP) | VAF 307/650 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51119234; called by muse, mutect2, varscan2
- GRM2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs138359683; called by muse, mutect2, varscan2
- GRM5 | c.3569G>A p.C1190Y (on ENST00000305447 / NM_001143831.2; = p.C1158Y on NM_000842.4) | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs200248896; called by muse, mutect2, varscan2
- GSTO2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58539408, COSV58539437; called by muse, mutect2, varscan2
- GTF3C1 | c.863G>T p.R288M | Missense Mutation (SNP) | VAF 182/419 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62244330; called by muse, mutect2, varscan2
- GUCY1A1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs139449524; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 79/118 reads (67%) | catalogued as COSV54945907; called by mutect2, varscan2
- H1-5 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 169/321 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as COSV58901776; called by muse, mutect2, varscan2
- H3-4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 236/467 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs545672641, COSV64210693; called by muse, mutect2, varscan2
- HABP2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 178/399 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs372640275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC4 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 226/465 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs147050291; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 69/171 reads (40%) | catalogued as rs754540615; called by mutect2, pindel, varscan2
- HECTD4 | c.5923C>T p.R1975W | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66389252; called by muse, mutect2, varscan2
- HELZ2 | c.6208G>A p.V2070I (on ENST00000467148 / NM_001037335.2; = p.V1501I on NM_033405.3) | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760698832; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HIBADH | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 124/316 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs747333479; called by muse, mutect2, varscan2
- HIC1 | c.179C>T p.A60V (on ENST00000322941 / NM_001098202.1; = p.A41V on NM_006497.4) | Missense Mutation (SNP) | VAF 146/277 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53971826; called by muse, mutect2, varscan2
- HIP1R | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs770074345, COSV53441847; called by muse, mutect2, varscan2
- HK3 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781656943; called by muse, mutect2, varscan2
- HLA-DOA | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1168523284; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 56/106 reads (53%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXB3 | c.924C>A p.Y308* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV100290464; called by muse, mutect2, varscan2
- HPS1 | c.852del p.S285Afs*46 | Frame Shift Del (DEL) | VAF 232/506 reads (46%) | catalogued as rs757883936, COSV57268431; called by mutect2, varscan2
- HPS4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs141684342; called by muse, mutect2, varscan2
- HS3ST4 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 152/272 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58818259; called by muse, mutect2, varscan2
- HSPB7 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 23/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280039361; called by muse, mutect2
- HTT | c.8651G>A p.R2884H | Missense Mutation (SNP) | VAF 270/578 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1193396566; called by muse, mutect2, varscan2
- ICAM4 | c.38del p.L13Wfs*40 | Frame Shift Del (DEL) | VAF 28/57 reads (49%) | catalogued as rs753968171; called by mutect2, varscan2
- ID3 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs934808402; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 110/228 reads (48%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IGHA1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 223/955 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.317); catalogued as rs587686108; called by muse, mutect2, varscan2
- IGHA1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 202/454 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs766451356; called by muse, mutect2
- IKBIP | c.626del p.N209Ifs*3 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | catalogued as rs752553685; called by mutect2, pindel, varscan2
- IKZF3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs778371145, COSV53108210; called by muse, mutect2, varscan2
- ILDR2 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 130/246 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1429220005; called by muse, varscan2
- INPP5F | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs374196186; called by muse, mutect2, varscan2
- INSL4 | c.338del p.K113Rfs*15 | Frame Shift Del (DEL) | VAF 138/322 reads (43%) | catalogued as rs754904296; called by mutect2, pindel, varscan2
- INSRR | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 339/723 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753223410, COSV100948270, COSV63876504; called by muse, mutect2, varscan2
- IRS4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64532834; called by muse, mutect2, varscan2
- IRX3 | c.1113del p.S372Lfs*151 | Frame Shift Del (DEL) | VAF 48/155 reads (31%) | catalogued as rs759120276; called by pindel, varscan2
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 134/289 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2, varscan2
- ITLN1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as rs369419342; called by muse, mutect2, varscan2
- JUP | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 216/486 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as rs199597864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KALRN | c.2855C>T p.T952M | Missense Mutation (SNP) | VAF 164/335 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532130353, COSV53774491; called by muse, mutect2, varscan2
- KANSL1L | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768167130; called by muse, mutect2, varscan2
- KAT6B | c.3763G>A p.G1255S | Missense Mutation (SNP) | VAF 148/346 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.09); catalogued as rs147574112, COSV54744307; called by muse, mutect2, varscan2
- KATNIP | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759936156; called by muse, mutect2, varscan2
- KCNK13 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56411835; called by muse, mutect2, varscan2
- KCNK3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV57192669; called by muse, mutect2, varscan2
- KCNQ4 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 193/408 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs551509351; called by muse, mutect2, varscan2
- KCTD3 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as rs780870230; called by muse, mutect2, varscan2
- KIAA0753 | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1305713684; called by muse, mutect2, varscan2
- KIF1A | c.4609C>T p.R1537W (on ENST00000320389 / NM_001379639.1; = p.R1529W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs202072706; called by muse, mutect2, varscan2
- KIF1C | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1304103979; called by muse, mutect2, varscan2
- KIF20A | c.1210C>T p.L404= | Splice Region (SNP) | VAF 70/125 reads (56%) | catalogued as COSV54730425; called by muse, mutect2, varscan2
- KIF7 | c.1640del p.G547Afs*5 | Frame Shift Del (DEL) | VAF 138/372 reads (37%) | catalogued as rs770571299, CX113624; called by pindel, varscan2
- KLF4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65929726; called by muse, mutect2, varscan2
- KLHL28 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as rs768808809, COSV61888595; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLKB1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs770012003; called by muse, mutect2, varscan2
- KMT2A | c.4991G>A p.R1664Q | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs782779521, COSV100628365; called by muse, mutect2, varscan2
- KMT2C | c.5746A>G p.R1916G | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139187039, COSV104384286, COSV51395976; called by muse, mutect2, varscan2
- KMT2D | c.6700C>A p.P2234T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV56423055; called by muse, mutect2, varscan2
- KRT12 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs970668837; called by muse, mutect2
- KRT5 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 233/455 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as rs759651620; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 47/94 reads (50%) | catalogued as rs750491454; called by mutect2, varscan2
- L3MBTL4 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 85/224 reads (38%) | catalogued as COSV53131746; called by muse, mutect2, varscan2
- LAMA5 | c.4132G>A p.V1378M | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs199705177; called by muse, mutect2, varscan2
- LAMB1 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs771248391, COSV55962713; called by muse, mutect2, varscan2
- LARGE1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1220026937; called by muse, mutect2, varscan2
- LBX2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 239/520 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs1406997879; called by muse, mutect2, varscan2
- LCN8 | c.155C>T p.P52L (on ENST00000612714 / NM_001345934.1; = p.P29L on NM_178469.3) | Missense Mutation (SNP) | VAF 209/474 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs748907314, COSV100293414; called by muse, mutect2, varscan2
- LCT | c.4688C>T p.A1563V | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs755411378; called by muse, mutect2, varscan2
- LENG1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs111616066; called by muse, mutect2, varscan2
- LGI3 | c.26del p.G9Afs*61 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | catalogued as rs894404355; called by mutect2, pindel, varscan2
- LGR5 | c.1938del p.F646Lfs*21 | Frame Shift Del (DEL) | VAF 81/498 reads (16%) | catalogued as COSV57010048; called by mutect2, pindel, varscan2
- LIX1L | c.204del p.G69Afs*17 | Frame Shift Del (DEL) | VAF 89/236 reads (38%) | catalogued as rs781851782; called by mutect2, pindel, varscan2
- LMNTD2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374252641; called by muse, mutect2, varscan2
- LMX1B | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 66/481 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs774910309; called by muse, mutect2, varscan2
- LONP2 | c.898del p.M300Cfs*10 | Frame Shift Del (DEL) | VAF 38/88 reads (43%) | catalogued as rs745798174, COSV99035475; called by mutect2, varscan2
- LPO | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.838); catalogued as rs1269738174, COSV51862940; called by muse, mutect2, varscan2
- LRFN5 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747782144, COSV53253065; called by muse, mutect2, varscan2
- LRIG3 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as COSV57868101; called by muse, mutect2, varscan2
- LRRC29 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 174/350 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1452925447; called by muse, mutect2, varscan2
- LRRC59 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 124/277 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs751372015, COSV56813971; called by muse, mutect2, varscan2
- LRRC7 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs143210018; called by muse, varscan2
- LRTM1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 122/259 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs372903003, COSV55558000; called by muse, mutect2, varscan2
- LTBP4 | c.4861C>T p.R1621W (on ENST00000308370 / NM_001042544.1; = p.R1584W on NM_003573.2) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs763712345; called by muse, mutect2, varscan2
- LTN1 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs533578641; called by muse, mutect2, varscan2
- LYRM4 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 147/321 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57993551, COSV57994394; called by muse, mutect2, varscan2
- MAMDC4 | c.2863G>A p.V955M (on ENST00000445819; = p.V876M on NM_206920.3) | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs374689216; called by muse, mutect2
- MAML3 | c.2897G>T p.R966M | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV72209502; called by muse, mutect2, varscan2
- MANBA | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 223/482 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362274518; called by muse, mutect2, varscan2
- MAP3K11 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV58420352; called by muse, mutect2, varscan2
- MAP3K19 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs373039984; called by muse, mutect2, varscan2
- MAP3K6 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs763441636, COSV100539348; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 36/76 reads (47%) | catalogued as rs765962881; called by mutect2, varscan2
- MARK1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs779247133, COSV65067330; called by muse, mutect2, varscan2
- MASP2 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs372314306; called by muse, mutect2, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 195/452 reads (43%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MCC | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as rs756020358, COSV56723849; called by muse, mutect2, varscan2
- MCM7 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs758673969; called by muse, mutect2, varscan2
- MEIOB | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1025418947; called by muse, mutect2, varscan2
- MELTF | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 191/440 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773072645; called by muse, mutect2, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs760012501; called by mutect2, varscan2
- METTL24 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 129/222 reads (58%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.034); catalogued as rs952371913; called by muse, mutect2, varscan2
- MEX3B | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV61663399; called by muse, mutect2, varscan2
- MFAP3 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.087); catalogued as rs543278918, COSV59457142; called by mutect2, varscan2
- MFGE8 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 217/379 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760298574, COSV51558228; called by muse, mutect2, varscan2
- MGAT5B | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139971041; called by muse, mutect2, varscan2
- MGLL | c.421G>A p.G141S (on ENST00000398104 / NM_001003794.2; = p.G151S on NM_007283.6) | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1470451682; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIER1 | c.1201A>G p.N401D (on ENST00000355356 / NM_001077701.3; = p.N418D on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1450120541; called by muse, mutect2, varscan2
- MLYCD | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 163/361 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV52304066; called by muse, mutect2, varscan2
- MMUT | c.2101T>C p.C701R | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as CD060617; called by muse, mutect2, varscan2
- MN1 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as rs746306235, COSV100179606; called by muse, mutect2, varscan2
- MNX1 | c.336del p.H114Tfs*108 | Frame Shift Del (DEL) | VAF 14/20 reads (70%) | catalogued as rs1327737533, CD003849; called by mutect2, varscan2
- MOGAT3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs767154824, COSV56175579; called by muse, mutect2, varscan2
- MON1B | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569161651, COSV99941803; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 63/145 reads (43%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MORC2 | c.713G>A p.R238H (on ENST00000397641 / NM_001303256.3; = p.R176H on NM_014941.3) | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs367766290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH5 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 145/332 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs371019146; called by muse, mutect2, varscan2
- MROH7 | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs777096703; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/189 reads (31%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MS4A1 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 212/422 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs777874424, COSV100619449; called by muse, mutect2, varscan2
- MS4A18 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs534337923, COSV67517736; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 44/80 reads (55%) | catalogued as COSV60305229; called by mutect2, varscan2
- MTUS2 | c.3308G>A p.R1103Q (on ENST00000612955 / NM_001366650.1; = p.R82Q on NM_015233.6) | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as rs557221814; called by muse, mutect2, varscan2
- MUC16 | c.34931C>T p.T11644I | Missense Mutation (SNP) | VAF 161/319 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.577); catalogued as rs866459974; called by muse, mutect2, varscan2
- MUC17 | c.4158G>A p.M1386I | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs527882807, COSV60281963, COSV60285495, COSV60303856; called by muse, mutect2, varscan2
- MXRA7 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 106/220 reads (48%) | PolyPhen possibly damaging (0.581); catalogued as rs1388582625; called by muse, mutect2, varscan2
- MXRA8 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 157/300 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1322367962, COSV58510198; called by muse, mutect2, varscan2
- MYH7 | c.5689C>T p.R1897C | Missense Mutation (SNP) | VAF 256/514 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756655803, COSV62524771; called by muse, mutect2, varscan2
- NADK2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs779870872, COSV56937946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAP1L3 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 110/112 reads (98%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV59076801; called by muse, varscan2
- NAXD | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 82/183 reads (45%) | catalogued as rs751472798; called by muse, mutect2, varscan2
- NBEAL1 | c.6712G>A p.V2238I | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs762733158; called by muse, mutect2, varscan2
- NBPF10 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 146/676 reads (22%) | catalogued as rs782117009, COSV61670355; called by muse, mutect2, varscan2
- NCOR2 | c.5291C>T p.A1764V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs777397769, COSV100656912; called by muse, mutect2, varscan2
- NEB | c.10657G>A p.A3553T | Missense Mutation (SNP) | VAF 167/372 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs749327025; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 49/121 reads (40%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEU1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 227/494 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1263545300, COSV57666522; called by muse, mutect2, varscan2
- NEURL1B | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs1420440418; called by muse, mutect2, varscan2
- NEURL4 | c.3300del p.S1101Vfs*78 | Frame Shift Del (DEL) | VAF 74/216 reads (34%) | catalogued as rs1567619937; called by mutect2, pindel, varscan2
- NEUROG2 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100511859; called by muse, mutect2, varscan2
- NF1 | c.4384C>T p.R1462W (on ENST00000358273 / NM_001042492.3; = p.R1441W on NM_000267.3) | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.937); catalogued as rs876658127, COSV62210511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFE2 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs777615884; called by muse, mutect2, varscan2
- NID1 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 168/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746516796, COSV51625828; called by muse, mutect2, varscan2
- NKX2-2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 294/637 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65819876; called by muse, mutect2, varscan2
- NLGN3 | c.713G>A p.R238Q (on ENST00000358741 / NM_181303.2; = p.R218Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104423798; called by muse, mutect2, varscan2
- NLRC3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs565215801, COSV100073226, COSV57093481; called by muse, mutect2, varscan2
- NLRP13 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 151/302 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs757810047; called by muse, mutect2, varscan2
- NOC3L | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs763109129, COSV64929629; called by muse, mutect2, varscan2
- NOCT | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs371556362; called by muse, mutect2, varscan2
- NOS2 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100569617; called by muse, mutect2, varscan2
- NPHP4 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1270711258, COSV65395169; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 37/110 reads (34%) | catalogued as rs1167519601; called by mutect2, pindel, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 58/130 reads (45%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN3 | c.2223del p.R742Vfs*8 (on ENST00000335750 / NM_001330195.2; = p.R369Vfs*8 on NM_004796.6) | Frame Shift Del (DEL) | VAF 88/216 reads (41%) | catalogued as COSV59808471; called by mutect2, pindel, varscan2
- NTAN1 | c.831dup p.H278Tfs*13 | Frame Shift Ins (INS) | VAF 64/214 reads (30%) | catalogued as rs780770021; called by mutect2, varscan2
- NUF2 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.468); catalogued as COSV54844592; called by muse, mutect2, varscan2
- NUP133 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs746331640, COSV54573927; called by muse, mutect2, varscan2
- NUP133 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs373640878; called by muse, mutect2, varscan2
- NUP214 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1172731606; called by muse, mutect2, varscan2
- NUP37 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219909718; called by muse, mutect2, varscan2
- NXPE2 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 122/287 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64940637; called by muse, mutect2, varscan2
- OBSCN | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 321/680 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52736812; called by muse, mutect2, varscan2
- OR10H3 | c.311_313del p.F104del | In Frame Del (DEL) | VAF 78/238 reads (33%) | catalogued as rs968753741; called by pindel, varscan2
- OR4D11 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100506668, COSV57585156; called by muse, mutect2, varscan2
- OR4K2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 124/669 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53849706, COSV53850667; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 167/362 reads (46%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5K4 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs547691527; called by muse, mutect2, varscan2
- OR5M1 | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs778190661; called by muse, varscan2
- OR5M1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs375403564; called by muse, varscan2
- OR9A4 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV71885570; called by muse, mutect2, varscan2
- OR9I1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV56926412; called by muse, mutect2, varscan2
- OTOF | c.4658T>C p.M1553T (on ENST00000272371 / NM_194248.3; = p.M786T on NM_004802.4) | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV55505116; called by muse, mutect2, varscan2
- OTOP1 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs547040796; called by muse, mutect2
- P3H3 | c.50del p.P17Rfs*9 | Frame Shift Del (DEL) | VAF 21/163 reads (13%) | catalogued as rs1555120763; called by mutect2, pindel, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 74/177 reads (42%) | catalogued as rs763394045; called by mutect2, varscan2
- PAK6 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751329273; called by muse, mutect2, varscan2
- PALB2 | c.2359A>G p.T787A | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1567217510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAOX | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs771266490; called by muse, mutect2, varscan2
- PAPPA | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 196/432 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60291334; called by muse, mutect2, varscan2
- PAPPA2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749349114, COSV62772010; called by muse, mutect2, varscan2
- PCDHA1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.045); catalogued as rs782409216, COSV65375342; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 196/450 reads (44%) | catalogued as rs558931090, COSV65368078; called by mutect2, varscan2
- PCDHA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 324/692 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65342498; called by muse, mutect2, varscan2
- PCDHAC1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53850275; called by muse, mutect2, varscan2
- PCDHB7 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.386); catalogued as rs782021995, COSV50793324; called by muse, mutect2, varscan2
- PCDHGA5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 191/374 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV54014928; called by muse, mutect2, varscan2
- PCDHGB1 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 162/348 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs749766771, COSV99547547; called by muse, mutect2, varscan2
- PCLO | c.12815G>A p.R4272H | Missense Mutation (SNP) | VAF 182/426 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61658525; called by muse, mutect2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 89/175 reads (51%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCLO | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs779246634; called by muse, mutect2, varscan2
- PDCD6 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs201011657, COSV53781121; called by muse, mutect2
- PDZD4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1239111791; called by muse, mutect2, varscan2
- PENK | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV59242866; called by muse, mutect2, varscan2
- PEX1 | c.1883A>G p.D628G | Missense Mutation (SNP) | VAF 129/310 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99952235; called by muse, mutect2, varscan2
- PFKP | c.1981G>A p.V661M | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs778669961, COSV56528309; called by muse, mutect2, varscan2
- PHRF1 | c.2465C>T p.T822M (on ENST00000264555 / NM_001286581.2; = p.T821M on NM_020901.4) | Missense Mutation (SNP) | VAF 167/352 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs201479751; called by muse, mutect2, varscan2
- PIEZO1 | c.7189G>C p.A2397P | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as rs765524996; called by muse, mutect2, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 89/237 reads (38%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PIK3CG | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 34/166 reads (20%) | catalogued as rs1448416221; called by muse, mutect2, varscan2
- PITPNM1 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs757915989; called by muse, mutect2, varscan2
- PKDREJ | c.4033G>A p.V1345I | Missense Mutation (SNP) | VAF 130/255 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs146200280, COSV53546483; called by muse, mutect2, varscan2
- PKN1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.124); catalogued as rs759249010, COSV54398783; called by muse, mutect2, varscan2
- PKNOX2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs772001614; called by muse, varscan2
- PLA2G4E | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1189015098; called by muse, mutect2, varscan2
- PLCB4 | c.1385del p.N462Tfs*4 | Frame Shift Del (DEL) | VAF 87/220 reads (40%) | catalogued as rs1489417610; called by mutect2, pindel, varscan2
- PLEC | c.10423G>A p.V3475I (on ENST00000322810 / NM_201380.4; = p.V3365I on NM_000445.5) | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1554679577, COSV59685407; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 128/264 reads (48%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHN1 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs771316845; called by muse, mutect2, varscan2
- PLIN5 | c.910A>G p.S304G | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs911014993; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 90/204 reads (44%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNB1 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866132965, COSV56488853; called by muse, mutect2, varscan2
- PLXND1 | c.3920C>T p.T1307M | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1327363739; called by muse, mutect2, varscan2
- PNMT | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99510550; called by muse, mutect2, varscan2
- PNPLA1 | c.874C>T p.R292C (on ENST00000394571 / NM_001374623.1; = p.R197C on NM_173676.2) | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776818332, COSV100462918; called by muse, mutect2, varscan2
- POGLUT2 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV65682799; called by muse, mutect2, varscan2
- POLD1 | c.537del p.R180Gfs*3 | Frame Shift Del (DEL) | VAF 90/267 reads (34%) | catalogued as COSV70957044; called by mutect2, pindel, varscan2
- POLI | c.1725dup p.Q576Tfs*10 | Frame Shift Ins (INS) | VAF 47/131 reads (36%) | catalogued as rs1370198071; called by mutect2, pindel, varscan2
- POMC | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 109/252 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53035169; called by muse, mutect2, varscan2
- POMC | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 148/315 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53034379; called by muse, mutect2, varscan2
- POU3F3 | c.326_346del p.A109_A115del | In Frame Del (DEL) | VAF 42/127 reads (33%) | catalogued as rs1373599433; called by mutect2, varscan2
- PPAN-P2RY11 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as rs771336005; called by muse, mutect2, varscan2
- PPP1R3A | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 301/572 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs755702039; called by muse, mutect2, varscan2
- PPP2R3B | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs139187986, COSV101180781; called by muse, mutect2, varscan2
- PRAMEF4 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 295/692 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs562920609, COSV52437653; called by muse, mutect2, varscan2
- PRDM1 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV64847185; called by muse, mutect2, varscan2
- PRKAG2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs182750960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKG1 | c.1967C>A p.A656E | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV100907226; called by muse, varscan2
- PRORP | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs978666601, COSV51616493; called by muse, mutect2, varscan2
- PRR23D1 | c.150dup p.P51Tfs*27 | Frame Shift Ins (INS) | VAF 37/192 reads (19%) | catalogued as rs769392464; called by mutect2, varscan2
- PRR36 | c.2476C>T p.Q826* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101607149; called by muse, mutect2
- PRRC2C | c.6696A>G p.I2232M (on ENST00000367742; = p.I2230M on NM_015172.4) | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs772534023; called by muse, mutect2, varscan2
- PRSS53 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 184/405 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs748276565, COSV99762675; called by muse, mutect2, varscan2
- PTBP3 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99270372; called by muse, mutect2, varscan2
- PTCD1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52868450; called by muse, mutect2, varscan2
- PTCH1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 304/616 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs1293146883, COSV59492626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 59/149 reads (40%) | catalogued as rs763413121; called by mutect2, pindel, varscan2
- R3HDM1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs763279314; called by muse, mutect2, varscan2
- RAB27A | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416818050; called by muse, mutect2, varscan2
- RAD51AP2 | c.357dup p.S120Lfs*5 | Frame Shift Ins (INS) | VAF 62/172 reads (36%) | catalogued as rs750569378; called by pindel, varscan2
- RAI1 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 434/876 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs780731931; called by muse, mutect2, varscan2
- RAPSN | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 265/558 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs773316367; called by muse, mutect2, varscan2
- RASGRF1 | c.625-2A>G p.X209_splice | Splice Site (SNP) | VAF 71/132 reads (54%) | catalogued as rs1247547616, COSV101369649; called by muse, mutect2, varscan2
- RASL12 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 128/283 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1216496113; called by muse, varscan2
- RASSF7 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 167/330 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs761343590, COSV60346370, COSV60348461; called by muse, mutect2, varscan2
- RECQL4 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1214615126; called by muse, mutect2, varscan2
- RELA | c.973del p.R325Gfs*31 | Frame Shift Del (DEL) | VAF 42/109 reads (39%) | catalogued as COSV58014620; called by mutect2, varscan2
- REPIN1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs763058642; called by muse, mutect2, varscan2
- RGL2 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 262/499 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs369642679; called by muse, mutect2, varscan2
- RGL4 | c.1089G>A p.A363= | Splice Region (SNP) | VAF 199/420 reads (47%) | catalogued as rs527600048, COSV99318676; called by muse, mutect2, varscan2
- RGPD8 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1365019478; called by mutect2, varscan2
- RIMS1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 172/354 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104393426; called by mutect2, varscan2
- RIMS2 | c.2458C>G p.Q820E (on ENST00000666250 / NM_001348490.2; = p.Q628E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51683094; called by muse, mutect2, varscan2
- RIPOR3 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs756540695; called by muse, mutect2, varscan2
- RMI1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 83/179 reads (46%) | catalogued as rs767370149, COSV57938024; called by muse, mutect2, varscan2
- RNF11 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 100/175 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54376119; called by muse, mutect2, varscan2
- ROR2 | c.1770del p.D591Tfs*32 | Frame Shift Del (DEL) | VAF 120/303 reads (40%) | catalogued as COSV65217415; called by mutect2, pindel, varscan2
- ROS1 | c.5743G>A p.G1915R | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs759091073, COSV63861219; called by muse, mutect2, varscan2
- RPGRIP1L | c.1571A>G p.K524R | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as COSV50915388; called by muse, mutect2, varscan2
- RTL4 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 36/36 reads (100%) | catalogued as COSV61206723, COSV61207433; called by muse, mutect2
- RUNX1T1 | c.273del p.S92Hfs*35 (on ENST00000265814 / NM_001198628.1; = p.S65Hfs*35 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/153 reads (39%) | catalogued as rs1258994032; called by mutect2, pindel, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as COSV62684236; called by mutect2, varscan2
- RYR3 | c.10174G>A p.A3392T (on ENST00000389232; = p.A3393T on NM_001036.6) | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1324444893, COSV66806005; called by muse, mutect2, varscan2
- SCN4B | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265062815, COSV61251899; called by muse, mutect2, varscan2
- SCN5A | c.1895C>T p.T632M | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as rs199473134, CM100662; ClinVar: not provided; called by muse, mutect2, varscan2
- SCUBE1 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749908505, COSV62611258, COSV62612465; called by muse, varscan2
- SDHAF3 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 61/147 reads (41%) | catalogued as rs531212069; called by muse, mutect2, varscan2
- SDS | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV57452830; called by muse, mutect2, varscan2
- SELP | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372978525; called by muse, mutect2, varscan2
- SEMA3A | c.1227G>C p.M409I | Missense Mutation (SNP) | VAF 134/289 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54880077; called by muse, mutect2, varscan2
- SEMA6B | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as rs1444539286; called by muse, mutect2, varscan2
- SENP6 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519169; called by muse, mutect2, varscan2
- SESN2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 170/335 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201255439; called by muse, mutect2, varscan2
- SETD3 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as rs1425852578; called by muse, mutect2, varscan2
- SETX | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs769702224; called by muse, mutect2, varscan2
- SEZ6L | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as rs1219092259; called by muse, mutect2, varscan2
- SF3A2 | c.869del p.P290Rfs*156 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1404234638; called by mutect2, pindel, varscan2
- SFMBT2 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62815298; called by muse, mutect2, varscan2
- SFSWAP | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1206172738, COSV104377397, COSV55525595; called by muse, mutect2, varscan2
- SFSWAP | c.870T>A p.D290E | Missense Mutation (SNP) | VAF 131/249 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1566008860, COSV55524453; called by muse, mutect2, varscan2
- SH3TC1 | c.3910G>A p.A1304T | Missense Mutation (SNP) | VAF 247/603 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429439203; called by muse, mutect2, varscan2
- SH3TC2 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 173/355 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs752002618, COSV60467211; called by muse, mutect2, varscan2
- SHANK1 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs755259005; called by muse, mutect2, varscan2
- SHROOM3 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as rs533202648; called by muse, mutect2, varscan2
- SIM1 | c.849G>A p.L283= | Splice Region (SNP) | VAF 17/128 reads (13%) | catalogued as COSV53489636; called by muse, mutect2, varscan2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2, varscan2
- SKI | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 189/388 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs770481744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 109/214 reads (51%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A3 | c.424del p.V142* | Frame Shift Del (DEL) | VAF 29/272 reads (11%) | catalogued as COSV52634575; called by mutect2, pindel, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 122/321 reads (38%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC16A3 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 147/307 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758543235; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 120/296 reads (41%) | catalogued as rs749849908; called by pindel, varscan2
- SLC25A19 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 247/545 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as rs758036010; called by muse, mutect2, varscan2
- SLC25A22 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 281/613 reads (46%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.671); catalogued as rs201932343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A23 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs767419223, COSV51192222; called by muse, mutect2
- SLC25A27 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64927959; called by muse, mutect2, varscan2
- SLC25A29 | c.448G>A p.V150I (on ENST00000359232 / NM_001039355.3; = p.V84I on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1448633005; called by muse, mutect2, varscan2
- SLC25A44 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs760375813, COSV63961470; called by muse, mutect2, varscan2
- SLC26A3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1455672221; called by muse, mutect2, varscan2
- SLC2A6 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs782059162; called by muse, mutect2, varscan2
- SLC2A8 | c.708del p.I237Sfs*27 | Frame Shift Del (DEL) | VAF 49/124 reads (40%) | catalogued as rs199808560; called by mutect2, pindel
- SLC32A1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 290/567 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs1023170011, COSV54148411; called by muse, mutect2, varscan2
- SLC4A2 | c.3091G>A p.G1031S | Missense Mutation (SNP) | VAF 69/498 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376108278; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC5A11 | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs985662857, COSV100762808; called by muse, varscan2
- SLC6A11 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 120/186 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1451859570; called by muse, mutect2, varscan2
- SLC6A3 | c.1639dup p.H547Pfs*56 | Frame Shift Ins (INS) | VAF 135/294 reads (46%) | catalogued as rs749320240; called by mutect2, varscan2
- SLCO1A2 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs937164998; called by muse, mutect2, varscan2
- SLIT2 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1347609350; called by muse, mutect2, varscan2
- SLITRK5 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1223202424; called by muse, varscan2
- SLITRK5 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.052); catalogued as rs777149211; called by muse, varscan2
- SLX4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 255/555 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs149779179; called by muse, mutect2, varscan2
- SMARCA4 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 308/582 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV60798787; called by muse, mutect2, varscan2
- SMC4 | c.1824del p.K608Nfs*15 | Frame Shift Del (DEL) | VAF 90/202 reads (45%) | catalogued as rs1038263749; called by mutect2, varscan2
- SMYD3 | c.877del p.I293Lfs*4 (on ENST00000490107 / NM_001375962.1; = p.I234Lfs*4 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 89/226 reads (39%) | catalogued as rs1558435001; called by mutect2, pindel, varscan2
- SNRNP200 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 198/404 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs750045583; called by muse, mutect2, varscan2
- SNX13 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV101285051; called by muse, mutect2, varscan2
- SNX17 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.062); catalogued as rs987619489; called by muse, mutect2, varscan2
- SNX18 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.276); catalogued as rs1355377115; called by muse, mutect2, varscan2
- SNX20 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 117/203 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs773010904; called by muse, mutect2, varscan2
- SOAT1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs751392105; called by muse, mutect2, varscan2
- SOCS6 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV101205780; called by muse, mutect2, varscan2
- SORCS1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs780091835, COSV99544512; called by muse, mutect2, varscan2
- SPATC1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs141080428; called by muse, mutect2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 140/371 reads (38%) | catalogued as rs752907815; called by mutect2, pindel, varscan2
- SPEN | c.6313del p.A2105Lfs*33 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as COSV65367511; called by mutect2, pindel, varscan2
- SPNS2 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 162/289 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs61732936; called by muse, mutect2, varscan2
- SPRYD7 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1455808810, COSV62524021; called by muse, mutect2, varscan2
- SPTA1 | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1485723850; called by muse, mutect2, varscan2
- SPTBN1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100776977; called by muse, mutect2, varscan2
- SPTBN4 | c.6854G>A p.R2285H | Missense Mutation (SNP) | VAF 215/464 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.511); catalogued as rs540578822, COSV58948969; called by muse, mutect2, varscan2
- SRCIN1 | c.3131G>A p.R1044H (on ENST00000621492; = p.R1010H on NM_025248.3) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1344314902; called by muse, mutect2, varscan2
- SRPK1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775640291, COSV60412861; called by muse, mutect2, varscan2
- SRRM3 | c.187del p.V63Wfs*11 | Frame Shift Del (DEL) | VAF 67/191 reads (35%) | catalogued as COSV58385820; called by mutect2, pindel, varscan2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs760883618; called by mutect2, varscan2
- STAB1 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373744584; called by muse, mutect2, varscan2
- STAC2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 154/374 reads (41%) | catalogued as rs143497706; called by muse, mutect2, varscan2
- STAG1 | c.1397G>T p.R466M | Missense Mutation (SNP) | VAF 132/262 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV99364729; called by muse, mutect2, varscan2
- STAG3 | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs768824588, COSV57927408; called by muse, mutect2, varscan2
- STAT6 | c.841dup p.Q281Pfs*92 | Frame Shift Ins (INS) | VAF 67/162 reads (41%) | catalogued as rs767674545; called by mutect2, varscan2
- STOX2 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1344767661; called by muse, mutect2, varscan2
- SUGP1 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.571); catalogued as rs754423277; called by muse, mutect2, varscan2
- SULF2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs769397181, COSV100737147, COSV63414734; called by muse, mutect2, varscan2
- SUPT6H | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1325940073; called by muse, mutect2, varscan2
- SWT1 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs780211031; called by muse, mutect2, varscan2
- SYMPK | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 143/264 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55613174; called by muse, mutect2, varscan2
- SYNPO | c.995G>C p.S332T (on ENST00000394243 / NM_001166208.2; = p.S88T on NM_007286.6) | Missense Mutation (SNP) | VAF 191/401 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56940091; called by muse, mutect2, varscan2
- SZT2 | c.9203G>A p.G3068D (on ENST00000634258 / NM_001365999.1; = p.G3011D on NM_015284.4) | Missense Mutation (SNP) | VAF 250/504 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65095383; called by muse, varscan2
- TACR2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149007484; called by muse, mutect2, varscan2
- TAF1 | c.4600C>T p.R1534C (on ENST00000373790 / NM_138923.4; = p.R1555C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52124656; called by muse, mutect2, varscan2
- TAF6 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs774023505; called by muse, varscan2
- TAL1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53745432; called by muse, mutect2, varscan2
- TAS1R3 | c.1812dup p.P605Afs*238 | Frame Shift Ins (INS) | VAF 147/323 reads (46%) | catalogued as rs777573279; called by mutect2, varscan2
- TBC1D8 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 190/371 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as rs760007379; called by muse, mutect2, varscan2
- TCF3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs549395259; called by muse, varscan2
- TCF3 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1239595896; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | catalogued as rs745872748; called by mutect2, varscan2
- TCTE1 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147193026; called by muse, mutect2, varscan2
- TDRKH | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 170/333 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200284470, COSV64316321; called by muse, mutect2, varscan2
- TEPSIN | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs781165082, COSV56143633; called by muse, mutect2, varscan2
- TESK1 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as rs769669483, COSV52411066; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1032A>T p.K344N | Missense Mutation (SNP) | VAF 118/246 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV51511886; called by muse, mutect2, varscan2
- TIGD4 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 64/135 reads (47%) | catalogued as rs761897713, COSV58550872; called by muse, mutect2, varscan2
- TIMELESS | c.2401C>T p.R801* | Nonsense Mutation (SNP) | VAF 46/88 reads (52%) | catalogued as COSV57511764; called by muse, varscan2
- TLX2 | c.292dup p.A98Gfs*269 | Frame Shift Ins (INS) | VAF 182/434 reads (42%) | catalogued as rs1238341034; called by mutect2, varscan2
- TLX3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 222/428 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766623983; called by muse, mutect2, varscan2
- TMEM104 | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100120745; called by muse, mutect2, varscan2
- TMEM121 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 249/517 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555444261, COSV101180046; called by muse, mutect2, varscan2
- TMEM132D | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.167); catalogued as rs1363837094; called by muse, mutect2, varscan2
- TMEM184A | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 179/374 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs376411588; called by muse, mutect2, varscan2
- TMEM200A | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775367537; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 44/100 reads (44%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 120/249 reads (48%) | catalogued as rs770800449; called by mutect2, varscan2
- TMTC3 | c.1554dup p.Y519Ifs*8 | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | catalogued as rs746894544; called by mutect2, pindel
- TNFRSF11A | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763222674; called by muse, mutect2, varscan2
- TNFRSF12A | c.149T>C p.M50T | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1303756048; called by muse, mutect2, varscan2
- TNRC18 | c.1505del p.P502Rfs*88 | Frame Shift Del (DEL) | VAF 184/382 reads (48%) | catalogued as rs759798146; called by mutect2, varscan2
- TNRC6A | c.3547del p.R1183Gfs*7 | Frame Shift Del (DEL) | VAF 35/64 reads (55%) | catalogued as rs1182016487; called by mutect2, varscan2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 173/436 reads (40%) | catalogued as CD126191; called by mutect2, pindel, varscan2
- TP53 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52750141, COSV52756133, COSV52784543, COSV52863408; called by muse, varscan2
- TPCN2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146072177, COSV53732832; called by muse, mutect2, varscan2
- TRHDE | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1268997017, COSV53838461; called by muse, mutect2, varscan2
- TRHDE | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.387); catalogued as rs761967037, COSV53840193; called by muse, mutect2, varscan2
- TRIM2 | c.1583G>A p.R528H (on ENST00000437508; = p.R555H on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/314 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755651013, COSV58632353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM42 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 156/277 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880822, COSV53883667; called by muse, mutect2, varscan2
- TRIM42 | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1309145653; called by muse, mutect2, varscan2
- TRIM43B | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 59/440 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1270859796; called by muse, mutect2, varscan2
- TRIOBP | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 121/217 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV60375355; called by muse, mutect2, varscan2
- TRMT44 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764705950; called by muse, varscan2
- TRPC6 | c.2408A>G p.K803R | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.169); catalogued as rs750525727; called by muse, mutect2, varscan2
- TSKU | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.155); catalogued as rs778133201, COSV60751385; called by muse, varscan2
- TSPAN16 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750213552, COSV57441837; called by muse, mutect2, varscan2
- TSPOAP1 | c.2267del p.G756Afs*23 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | catalogued as rs1463036794; called by mutect2, pindel, varscan2
- TTC21B | c.3545G>A p.R1182H | Missense Mutation (SNP) | VAF 260/594 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs199658616, COSV54627885; called by muse, mutect2, varscan2
- TTC24 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV63998120; called by muse, mutect2, varscan2
- TTC3 | c.4674del p.K1558Nfs*13 | Frame Shift Del (DEL) | VAF 61/157 reads (39%) | catalogued as rs1388042759; called by mutect2, pindel, varscan2
- TTC5 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs773124497, COSV51870906; called by muse, mutect2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 21/40 reads (53%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.70336G>A p.A23446T (on ENST00000591111; = p.A16022T on NM_003319.4) | Missense Mutation (SNP) | VAF 136/281 reads (48%) | PolyPhen possibly damaging (0.574); catalogued as rs759110420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB6 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV52313891; called by muse, mutect2, varscan2
- TUT7 | c.161del p.K54Rfs*3 | Frame Shift Del (DEL) | VAF 132/365 reads (36%) | catalogued as rs369091628; called by mutect2, pindel, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNRD3 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as rs763780159; called by muse, mutect2, varscan2
- TYK2 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 178/344 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs144995884; ClinVar: uncertain significance; called by muse, varscan2
- TYW1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148741933; called by muse, mutect2
- UBR7 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as rs779746473; called by muse, mutect2, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 118/302 reads (39%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- USH2A | c.10145T>C p.V3382A | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56375270; called by muse, mutect2, varscan2
- USP21 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs781514698; called by muse, mutect2, varscan2
- UTF1 | c.749del p.P250Rfs*26 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs898770563; called by mutect2, pindel, varscan2
- UTS2R | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 134/239 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032293895; called by muse, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs762976381; called by mutect2, varscan2
- VARS1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs762976775, COSV63304926; called by muse, mutect2, varscan2
- VCX3B | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 212/624 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as COSV66842742; called by muse, varscan2
- VIM | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 317/656 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749084801, COSV56407465; called by muse, mutect2, varscan2
- VPS18 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 113/239 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756789198, COSV55031528; called by muse, mutect2, varscan2
- VPS4B | c.341del p.K114Rfs*13 | Frame Shift Del (DEL) | VAF 82/235 reads (35%) | catalogued as rs750318908, COSV99448403; called by mutect2, pindel, varscan2
- VPS51 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 293/646 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs557757524; called by muse, mutect2, varscan2
- VPS51 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 257/559 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1316510985; called by muse, mutect2, varscan2
- VPS51 | c.1550del p.G517Vfs*42 | Frame Shift Del (DEL) | VAF 179/448 reads (40%) | catalogued as COSV99659530; called by mutect2, pindel, varscan2
- VSX2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 149/325 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1042589251; called by mutect2, varscan2
- VWA2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as rs368470047, COSV100073795; called by muse, varscan2
- WDFY4 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 177/389 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1256963585; called by muse, mutect2, varscan2
- WDFY4 | c.4595G>A p.G1532D | Missense Mutation (SNP) | VAF 109/199 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1323939717; called by muse, mutect2, varscan2
- WDR24 | c.2377C>T p.R793W (on ENST00000248142; = p.R663W on NM_032259.4) | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs146884857; called by muse, mutect2, varscan2
- WDR4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765182735, COSV57735954; called by muse, mutect2
- WDR62 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 283/505 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs752601653; called by muse, mutect2, varscan2
- WDR97 | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.071); catalogued as rs561414111, COSV100075519; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 165/179 reads (92%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFIKKN1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1161349733, COSV50194119; called by muse, mutect2, varscan2
- WHRN | c.680del p.G227Afs*32 | Frame Shift Del (DEL) | VAF 186/468 reads (40%) | catalogued as rs1306987034; called by mutect2, pindel, varscan2
- XPNPEP1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100450952; called by muse, mutect2, varscan2
- YBX2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 164/322 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs752018878; called by muse, mutect2, varscan2
- YLPM1 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs753261602, COSV53118501; called by muse, mutect2, varscan2
- ZBTB21 | c.2885A>G p.Q962R | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as rs950487773; called by muse, mutect2, varscan2
- ZBTB22 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs761674736; called by mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 96/196 reads (49%) | catalogued as COSV59691020; called by mutect2, varscan2
- ZBTB8A | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 147/352 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs757047444, COSV100331270; called by muse, mutect2, varscan2
- ZC3H11A | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 151/369 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs1172582430, COSV59745578; called by muse, mutect2, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 60/144 reads (42%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFHX4 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV50599698, COSV51505290; called by muse, mutect2, varscan2
- ZFP92 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1380528308, COSV58598651; called by muse, mutect2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 62/149 reads (42%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF16 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 184/355 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs144660752; called by muse, mutect2, varscan2
- ZNF208 | c.2891A>T p.K964M | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV68114748; called by muse, mutect2, varscan2
- ZNF225 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs895745901; called by muse, mutect2, varscan2
- ZNF28 | c.237T>A p.S79R | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs555939630; called by muse, mutect2, varscan2
- ZNF280D | c.2223del p.E742Kfs*62 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs1158517703; called by mutect2, pindel, varscan2
- ZNF292 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs191595173; called by muse, mutect2, varscan2
- ZNF385A | c.590C>T p.A197V (on ENST00000338010 / NM_001130967.3; = p.A177V on NM_015481.3) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233092399, COSV100566833; called by muse, mutect2, varscan2
- ZNF395 | c.700del p.H234Tfs*43 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | catalogued as rs768191349; called by mutect2, pindel
- ZNF420 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs768099738, COSV58493660; called by muse, mutect2, varscan2
- ZNF486 | c.372del p.G125Afs*22 | Frame Shift Del (DEL) | VAF 81/194 reads (42%) | catalogued as rs782415249; called by mutect2, pindel, varscan2
- ZNF513 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.031); catalogued as rs371030335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF516 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs944869081; called by muse, mutect2
- ZNF609 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.23); catalogued as COSV58582904; called by muse, mutect2, varscan2
- ZNF619 | c.1617del p.Q540Rfs*35 | Frame Shift Del (DEL) | VAF 42/109 reads (39%) | catalogued as rs1372461671; called by mutect2, pindel, varscan2
- ZNF629 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 212/452 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52697306; called by muse, mutect2, varscan2
- ZNF638 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 159/317 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs751043105, COSV52494988; called by muse, mutect2, varscan2
- ZNF678 | c.1358G>T p.R453I | Missense Mutation (SNP) | VAF 202/384 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as rs770822527; called by muse, mutect2, varscan2
- ZNF680 | c.1252T>C p.C418R | Missense Mutation (SNP) | VAF 134/266 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs1308175708; called by muse, mutect2, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | catalogued as rs781412139; called by mutect2, pindel, varscan2
- ZNF787 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1273033477, COSV99555331; called by muse, varscan2
- ZNF791 | c.1707dup p.H570Tfs*12 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs781098128; called by mutect2, varscan2
- ZNF831 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 100/174 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754843638, COSV64038317; called by muse, mutect2, varscan2
- ZNF839 | c.2239G>A p.V747M (on ENST00000558850 / NM_001267827.1; = p.V863M on NM_018335.5) | Missense Mutation (SNP) | VAF 99/188 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs746898107; called by muse, mutect2, varscan2
- ZNF99 | c.861T>G p.C287W | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766075534; called by muse, mutect2, varscan2
- ZXDB | c.1351del p.E451Rfs*22 | Frame Shift Del (DEL) | VAF 114/170 reads (67%) | catalogued as COSV66493619; called by mutect2, pindel, varscan2
- AANAT | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ABCA1 | c.4103T>C p.V1368A | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ABCA7 | c.5371del p.D1791Mfs*5 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- ABCB9 | c.1372dup p.C458Lfs*20 | Frame Shift Ins (INS) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.682A>G p.M228V | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ADAM12 | c.1973A>G p.H658R | Missense Mutation (SNP) | VAF 110/254 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADAMTS9 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADCK5 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
1,361 further variants in this file (635 protein-altering or splice-affecting, 411 silent, 315 other) are not listed here.
